Somatic mutation profile of tumor specimen TCGA-B5-A0K4-01A (aliquot TCGA-B5-A0K4-01A-11W-A062-09) from TCGA case TCGA-B5-A0K4, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 51.0 years (18,631 days).
Specimen TCGA-B5-A0K4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59a42f1c-7d77-474e-b193-592dad7a4d91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A0K4-10A (Blood Derived Normal), aliquot TCGA-B5-A0K4-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55a97557-2827-4ad9-8f67-250fbaa4aaed

The open-access MAF lists 58 somatic variants for this specimen: 48 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 8, Nonsense Mutation 7, Intron 2, Frame Shift Del 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 257/305 reads (84%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RRAS2 | c.216A>T p.Q72H | Missense Mutation (SNP) | VAF 345/555 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV56329221, COSV56329422; called by muse, mutect2, varscan2
- SOX17 | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52024163; called by muse, mutect2, varscan2
- ACTL8 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs376144648; called by muse, mutect2, varscan2
- APIP | c.608C>A p.T203K | Missense Mutation (SNP) | VAF 308/518 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV53506000; called by mutect2, varscan2
- ARHGEF38 | c.257A>G p.H86R | Missense Mutation (SNP) | VAF 112/250 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as rs775275752, COSV54440836; called by muse, mutect2
- ARID1A | c.4336C>T p.R1446* | Nonsense Mutation (SNP) | VAF 46/100 reads (46%) | catalogued as COSV61370903, COSV61383151; called by muse, mutect2, varscan2
- C9 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 119/266 reads (45%) | catalogued as rs144138616, CM970207; called by muse, mutect2, varscan2
- COL6A6 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 59/217 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs777327668, COSV62018072; called by muse, mutect2, varscan2
- DDX39B | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV58214098; called by muse, mutect2, varscan2
- FAM83B | c.2807G>A p.R936H | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757361359, COSV60919449; called by muse, mutect2, varscan2
- FGF14 | c.611C>A p.A204D | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV65936127; called by muse, mutect2, varscan2
- GABBR2 | c.1282T>G p.F428V | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.452); catalogued as COSV52293490; called by muse, mutect2, varscan2
- GMNN | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57776534; called by muse, mutect2, varscan2
- GNPTAB | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 152/322 reads (47%) | catalogued as COSV54776919; called by muse, mutect2, varscan2
- GPLD1 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.678); catalogued as rs144999503; called by muse, mutect2, varscan2
- ITGA2B | c.1958C>T p.P653L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs375936260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRTAP10-8 | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV58165956; called by muse, mutect2, varscan2
- LONRF3 | c.1600G>T p.E534* (on ENST00000371628 / NM_001031855.3; = p.E493* on NM_024778.5) | Nonsense Mutation (SNP) | VAF 44/125 reads (35%) | catalogued as COSV59149943; called by muse, mutect2, varscan2
- MUC17 | c.4901C>T p.T1634I | Missense Mutation (SNP) | VAF 102/447 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV60280362; called by muse, mutect2, varscan2
- MYO5C | c.2378A>T p.Q793L | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV55902631; called by muse, mutect2, varscan2
- NLRP3 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as rs769647268, CM1414461, COSV60220167; called by muse, mutect2, varscan2
- NSG1 | c.539C>A p.A180E | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.751); catalogued as COSV60371659, COSV60372907; called by muse, mutect2, varscan2
- NTAQ1 | c.317G>T p.C106F | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54873669; called by muse, mutect2, varscan2
- OTOGL | c.6955G>A p.E2319K (on ENST00000547103; = p.E2310K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54013233; called by muse, mutect2, varscan2
- OVCH1 | c.668C>A p.A223D | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58959700; called by muse, mutect2, varscan2
- PCDH7 | c.152T>C p.V51A | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV62336644; called by muse, mutect2, varscan2
- PLD5 | c.1349A>G p.Y450C (on ENST00000442594; = p.Y388C on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100138683, COSV59134055; called by muse, mutect2, varscan2
- PLEKHG1 | c.705_717del p.K236Lfs*7 | Frame Shift Del (DEL) | VAF 29/103 reads (28%) | catalogued as COSV62045106; called by mutect2, pindel, varscan2
- PRAMEF20 | c.222C>A p.C74* | Nonsense Mutation (SNP) | VAF 48/117 reads (41%) | catalogued as COSV57080579; called by muse, mutect2, varscan2
- PRDM9 | c.2564C>A p.T855K | Missense Mutation (SNP) | VAF 96/266 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV57002668; called by muse, mutect2, varscan2
- RAI2 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.357); catalogued as rs1185462411, COSV58963079; called by muse, mutect2, varscan2
- RNF31 | c.2062C>T p.R688W | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs985796955, COSV53758459; called by muse, mutect2, varscan2
- RP1 | c.3941C>T p.A1314V | Missense Mutation (SNP) | VAF 79/284 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs757560816, COSV55110306; called by muse, mutect2, varscan2
- SEC14L4 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.77); catalogued as rs769257410, COSV55398404; called by muse, mutect2, varscan2
- SLC28A2 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs1366623105, COSV61663240; called by muse, mutect2, varscan2
- SLC38A9 | c.485T>G p.L162R | Missense Mutation (SNP) | VAF 148/358 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59421637; called by muse, mutect2, varscan2
- SLC6A7 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57936903; called by muse, mutect2, varscan2
- SYT6 | c.745C>T p.R249C (on ENST00000610222 / NM_001366225.1; = p.R164C on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs558921980, COSV101059839, COSV65772455; called by muse, mutect2, varscan2
- TAX1BP1 | c.1147G>T p.V383L | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV55290560, COSV55291444; called by muse, mutect2, varscan2
- TMEM132B | c.2636C>T p.P879L | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs771932977, COSV54745077; called by muse, mutect2, varscan2
- TTC7B | c.2453C>T p.T818M | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs145873765; called by muse, mutect2, varscan2
- UBL4A | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs782395991, COSV54835566; called by muse, mutect2
- WDR36 | c.737G>A p.W246* | Nonsense Mutation (SNP) | VAF 32/71 reads (45%) | catalogued as COSV72411033; called by muse, mutect2, varscan2
- ANXA8 | c.278C>A p.P93Q | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- MAPK1IP1L | c.316_337del p.T106Qfs*30 | Frame Shift Del (DEL) | VAF 32/143 reads (22%) | called by mutect2, pindel, varscan2
- PIK3R3 | c.1188-13_1196del p.X396_splice | Splice Site (DEL) | VAF 39/128 reads (30%) | called by mutect2, pindel, varscan2
- ZSCAN30 | c.739dup p.I247Nfs*28 | Frame Shift Ins (INS) | VAF 86/264 reads (33%) | called by mutect2, pindel, varscan2
- FAM187B | c.300C>A p.G100= | Silent (SNP) | VAF 56/127 reads (44%) | catalogued as rs758254282, COSV61200924; called by muse, mutect2, varscan2
- FLNA | c.1833C>T p.F611= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV61037773; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1413G>A p.R471= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as COSV54560209; called by muse, mutect2, varscan2
- MAGEL2 | c.3498C>T p.Y1166= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV58565955; called by muse, mutect2, varscan2
- OR1A1 | c.678G>A p.Q226= | Silent (SNP) | VAF 206/473 reads (44%) | catalogued as rs1382156872, COSV58403133; called by muse, mutect2, varscan2
- PCLO | c.1962G>A p.P654= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as rs377565205; called by muse, mutect2, varscan2
- TUT7 | c.2616C>T p.G872= | Silent (SNP) | VAF 80/203 reads (39%) | catalogued as COSV52893491; called by muse, mutect2, varscan2
- ZC3H18 | c.75C>T p.D25= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs757695238, COSV56322659; called by muse, mutect2, varscan2
- EEF1B2 | c.398-173_398-170del | Intron (DEL) | VAF 10/76 reads (13%) | catalogued as rs760588035; called by pindel, varscan2
- THRB | c.284-12754C>T | Intron (SNP) | VAF 164/259 reads (63%) | catalogued as rs143423077, COSV54979147; called by muse, mutect2, varscan2
